Somatic mutation profile of tumor specimen TCGA-EB-A3XD-01A (aliquot TCGA-EB-A3XD-01A-22D-A23B-08) from TCGA case TCGA-EB-A3XD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 53.2 years (19,431 days).
Specimen TCGA-EB-A3XD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd9260a2-bae8-4aad-873d-f1282308320c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A3XD-10A (Blood Derived Normal), aliquot TCGA-EB-A3XD-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6d31646-d920-47ab-8001-c59808876ae8

The open-access MAF lists 385 somatic variants for this specimen: 251 protein-altering or splice-affecting, 125 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 125, Nonsense Mutation 15, RNA 6, Splice Region 4, Frame Shift Ins 1, 5'UTR 1, Intron 1, Translation Start Site 1, 5'Flank 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA12 | c.1643C>T p.A548V (on ENST00000272895 / NM_173076.3; = p.A230V on NM_015657.3) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1416496512, COSV55965571; called by muse, varscan2
- ACIN1 | c.2969C>T p.S990F | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52978204; called by muse, mutect2
- ACSL1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs995854397, COSV55664102; called by muse, mutect2
- ACSM3 | c.639-8C>T | Splice Region (SNP) | VAF 10/162 reads (6%) | catalogued as COSV55502338; called by muse, mutect2
- ADAM28 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as COSV56102175; called by muse, mutect2, varscan2
- ADAMTS7 | c.3413G>A p.G1138D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV66308133; called by muse, mutect2
- ADGRV1 | c.18254T>G p.V6085G | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV67989178; called by muse, mutect2, varscan2
- ADH1B | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.758); catalogued as COSV59297318; called by muse, mutect2
- AFAP1 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV61796730; called by muse, mutect2
- AGFG2 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 33/461 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53545932; called by muse, mutect2
- AGTR2 | c.401T>C p.F134S | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100903575, COSV100903639; called by muse, mutect2, varscan2
- AKAP3 | c.1948C>T p.L650F | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV57418012; called by muse, mutect2
- ALOX15 | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53396318; called by muse, mutect2
- ALPK2 | c.5284G>A p.E1762K | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs898482941, COSV64490476; called by muse, mutect2
- ALPP | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV101235207; called by muse, mutect2
- ARHGAP4 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV63132958, COSV63133366; called by muse, mutect2
- ASXL3 | c.5506G>A p.G1836R | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52469427; called by muse, mutect2, varscan2
- ATG2A | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs781519870, COSV65967408; called by muse, mutect2, varscan2
- ATP2A2 | c.2602C>T p.Q868* | Nonsense Mutation (SNP) | VAF 12/111 reads (11%) | catalogued as COSV57875726; called by muse, mutect2, varscan2
- AWAT1 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65738699; called by muse, mutect2, varscan2
- BICRAL | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); catalogued as COSV58406843; called by muse, mutect2, varscan2
- BIN1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52119848; called by muse, mutect2
- BIRC6 | c.8383C>T p.R2795* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV70202143; called by muse, mutect2
- C1QA | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as rs1334142146, COSV65889748; called by muse, mutect2
- C1QB | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59245627; called by muse, mutect2
- C4BPA | c.1136G>A p.R379K | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV65535976; called by muse, mutect2, varscan2
- C4orf50 | c.302G>A p.R101K (on ENST00000324058; = p.R1333K on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100136247; called by muse, mutect2
- CA2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs773013094, COSV53406436, COSV53408039; called by muse, mutect2
- CABIN1 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs370353524; called by muse, mutect2
- CALD1 | c.1645G>A p.E549K (on ENST00000361675 / NM_033138.4; = p.E294K on NM_004342.7) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs1192210180, COSV62649828; called by muse, mutect2
- CAVIN2 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV58424728; called by muse, mutect2, varscan2
- CCDC93 | c.308T>A p.L103Q | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60122379; called by muse, mutect2
- CCNA1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1273259772, COSV55222575; called by muse, mutect2
- CDO1 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147725758, COSV51665722; called by muse, mutect2
- CFAP126 | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.051); catalogued as COSV61368734; called by muse, mutect2, varscan2
- CHD8 | c.2347C>T p.P783S (on ENST00000646647 / NM_001170629.2; = p.P504S on NM_020920.4) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV67870146, COSV67871471; called by muse, mutect2
- CHRNA9 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs758963649, COSV59574152, COSV59575686; called by muse, mutect2, varscan2
- CMYA5 | c.5533G>A p.D1845N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as COSV71407192; called by muse, mutect2, varscan2
- CMYA5 | c.5999T>C p.V2000A | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV71407197; called by muse, mutect2
- CNGA2 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV61705230; called by muse, mutect2
- CNOT4 | c.1951C>T p.P651S (on ENST00000541284 / NM_001190850.1; = p.P577S on NM_013316.4) | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV64158562; called by muse, mutect2
- COL12A1 | c.7310C>T p.S2437F | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59399896; called by muse, mutect2
- COL3A1 | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV58591831; called by muse, mutect2, varscan2
- COL3A1 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV58591852; called by muse, mutect2
- COL7A1 | c.6323G>A p.G2108E | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355300196, COSV60397826; called by muse, mutect2
- COQ5 | c.50G>A p.W17* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV56019632; called by muse, mutect2
- CORIN | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs751259747, COSV56688042; called by muse, mutect2, varscan2
- CPXM1 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.39); catalogued as COSV66046013; called by muse, mutect2
- CPZ | c.1543G>A p.G515S (on ENST00000360986 / NM_001014447.3; = p.G504S on NM_003652.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs138232433; called by mutect2, varscan2
- CREBBP | c.7067C>T p.S2356F | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV52129905; called by muse, mutect2, varscan2
- CRK | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV56031277; called by muse, mutect2
- DEFB125 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV66703111; called by muse, mutect2
- DMD | c.3767G>A p.G1256E | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV63769596; called by muse, mutect2, varscan2
- DNAH5 | c.13045G>A p.D4349N | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV54224813, COSV54256382; called by muse, mutect2, varscan2
- DNAH5 | c.7664C>T p.T2555I | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54208694, COSV54236561; called by muse, mutect2
- DOCK4 | c.3260C>T p.P1087L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV69854890; called by muse, mutect2
- DRAXIN | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV53844105; called by muse, mutect2
- DRD3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.06); catalogued as COSV55681125, COSV55681746; called by muse, mutect2, varscan2
- DSP | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV65793792; called by muse, mutect2
- DSP | c.6047G>A p.G2016E | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs771165835, COSV65790899; called by muse, mutect2
- DTD1 | c.409A>C p.N137H | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66280396; called by muse, mutect2
- DUS3L | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV57832430, COSV57832502; called by muse, mutect2, varscan2
- EBF1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1434366358, COSV58185070; called by muse, mutect2, varscan2
- EEA1 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV59287347; called by muse, mutect2
- EGF | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as rs142198895; called by muse, mutect2, varscan2
- EHMT1 | c.2548G>A p.G850S | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71778021; called by muse, mutect2, varscan2
- EMILIN2 | c.1715A>G p.E572G | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV54425126; called by muse, mutect2
- ESRRG | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63168403; called by muse, mutect2
- FAM214B | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV59716739; called by muse, mutect2, varscan2
- FAM47C | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV63728054; called by muse, mutect2, varscan2
- FBN2 | c.5972T>A p.F1991Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV52525414; called by muse, mutect2
- FBXO43 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV71054615; called by muse, mutect2, varscan2
- FCHO1 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746345884, COSV53181755; called by muse, mutect2
- FGD1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64309064; called by muse, mutect2
- FLG | c.7411G>A p.G2471R | Missense Mutation (SNP) | VAF 117/953 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.048); catalogued as rs528687560, COSV64244027; called by muse, mutect2, varscan2
- FLG | c.5468G>A p.G1823E | Missense Mutation (SNP) | VAF 32/998 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1176615319, COSV64244031, COSV64245856; called by muse, mutect2
- FLRT3 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54009663; called by muse, mutect2
- FMNL2 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as COSV56490899; called by muse, mutect2
- FRAS1 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1295759844, COSV53624442, COSV53624523; called by muse, mutect2
- FRMPD2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59719860; called by muse, mutect2, varscan2
- GALR2 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57163480; called by muse, mutect2, varscan2
- GIMAP8 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs750008473, COSV56231017; called by muse, mutect2, varscan2
- GLI2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.051); catalogued as COSV58040941; called by muse, mutect2
- GNB5 | c.473C>T p.S158L (on ENST00000261837 / NM_016194.4; = p.S116L on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1185317282, COSV55900032; called by muse, mutect2, varscan2
- GPR151 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV57036035, COSV57038878; called by muse, mutect2
- GRIA1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377273074; called by muse, mutect2, varscan2
- GRM6 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV51445322; called by muse, mutect2
- GRM7 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV63133111, COSV63145884; called by muse, mutect2
- H2BW1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs782445882, COSV54220675; called by muse, mutect2
- HCFC1 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1427764465, COSV60074441; called by muse, mutect2
- HCN1 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1477444033, COSV100301983, COSV57520811; called by muse, mutect2
- HDAC9 | c.3125C>T p.S1042F (on ENST00000441542 / NM_178425.3; = p.S1039F on NM_178423.3) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV67772882, COSV67777491; called by muse, mutect2, varscan2
- HECTD4 | c.3380A>G p.N1127S | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV61180338; called by muse, mutect2
- HELZ2 | c.7717G>A p.D2573N (on ENST00000467148 / NM_001037335.2; = p.D2004N on NM_033405.3) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64443069; called by muse, mutect2
- HEMGN | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs1451210817, COSV52326091; called by muse, mutect2, varscan2
- HEMK1 | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51750990; called by muse, mutect2
- HS3ST2 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54462926; called by muse, mutect2, varscan2
- HTATSF1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV54479732; called by muse, mutect2
- ICE1 | c.4312C>T p.Q1438* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | catalogued as COSV56828202; called by muse, mutect2
- INSC | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.459); catalogued as rs751017681, COSV101089800; called by muse, mutect2, varscan2
- IRGC | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV54985004; called by muse, mutect2, varscan2
- ISX | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV58087414; called by muse, mutect2
- ITPR2 | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV67271844; called by muse, mutect2
- JAG2 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs1566766227, COSV59306779; called by muse, mutect2
- KCNE1 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61606322, COSV61607050; called by mutect2, varscan2
- KIF1A | c.2238G>A p.K746= | Splice Region (SNP) | VAF 10/266 reads (4%) | catalogued as COSV57493886; called by muse, mutect2
- KIF4A | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV65544319; called by muse, mutect2, varscan2
- KIF4B | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as COSV101469140, COSV70530197; called by muse, mutect2
- KLHL13 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as COSV53249827; called by muse, mutect2
- KMT2A | c.5321C>T p.S1774F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63288285; called by muse, mutect2
- KRT73 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs773161478, COSV59837692, COSV59840769; called by muse, mutect2, varscan2
- KRTAP24-1 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV100447573; called by muse, mutect2
- LAMP5 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55716920; called by muse, mutect2
- LAS1L | c.1919T>C p.V640A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV56707911; called by muse, mutect2, varscan2
- LDHD | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.018); catalogued as rs901517367, COSV55581324; called by muse, mutect2, varscan2
- LDLR | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as CM066908, COSV52944315; called by muse, mutect2, varscan2
- LMNA | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV100738920; called by muse, mutect2
- LRRC3B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as rs865841768, COSV67520179, COSV67522722; called by muse, mutect2
- LRRC8C | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64999341; called by muse, mutect2
- LTF | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.583); catalogued as rs759537818, COSV51609708; called by muse, mutect2
- MAGEC1 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV53570847; called by muse, mutect2, varscan2
- MAML3 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV59076046; called by muse, mutect2
- MAPK10 | c.505G>A p.D169N (on ENST00000359221 / NM_001351625.2; = p.D207N on NM_002753.5) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60386357; called by muse, mutect2, varscan2
- MATK | c.595G>A p.D199N (on ENST00000310132 / NM_139355.3; = p.D200N on NM_002378.4) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59555528; called by muse, mutect2, varscan2
- MMP27 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.363); catalogued as COSV52781597; called by muse, mutect2
- MPL | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs776753502, COSV65244366; called by muse, mutect2, varscan2
- MROH2B | c.4204G>A p.D1402N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV68186129; called by muse, mutect2
- MROH5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV71302126; called by muse, mutect2, varscan2
- MRPL53 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV50688658; called by muse, mutect2
- MRPS9 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51520482; called by muse, mutect2, varscan2
- MSLN | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 23/321 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV67020236; called by muse, mutect2
- MUC16 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as rs1222761973, COSV67477107; called by muse, mutect2
- MUC17 | c.9493C>T p.P3165S | Missense Mutation (SNP) | VAF 84/961 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV60294254; called by muse, mutect2
- MUC17 | c.13148A>G p.N4383S | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV60294263; called by muse, mutect2
- MXRA5 | c.8212G>A p.E2738K | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs974470737, COSV54240766; called by muse, mutect2
- MYH13 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV52834079; called by muse, mutect2, varscan2
- MYH4 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55116787; called by muse, mutect2
- MYH8 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101238448, COSV67959805; called by muse, mutect2
- MYLK | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs947470085, COSV60623288; called by muse, mutect2
- MYO1F | c.3073G>A p.G1025R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57796967; called by muse, mutect2
- NAIF1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.175); catalogued as COSV66091432; called by muse, mutect2, varscan2
- NBEA | c.8259G>A p.W2753* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | catalogued as COSV59798715; called by muse, mutect2
- NEK10 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV55355293; called by muse, mutect2
- NEO1 | c.3947C>T p.S1316L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.754); catalogued as rs1240753781, COSV56067272; called by muse, mutect2
- NFKB2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as rs1199544226, COSV51873188; called by muse, mutect2, varscan2
- NHEJ1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV59430904; called by muse, mutect2
- NLRP10 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100149618, COSV60779895; called by muse, mutect2
- NLRP13 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1159905879, COSV61622709; called by muse, mutect2, varscan2
- NLRP13 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.103); catalogued as COSV61622714; called by muse, mutect2, varscan2
- NOVA1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1200412725, COSV57472189; called by muse, mutect2
- NPC1 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1435915496, CM032617, COSV52580644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUDT15 | c.357T>C p.S119= | Splice Region (SNP) | VAF 10/101 reads (10%) | catalogued as rs757230015, COSV51642501; called by muse, mutect2
- OAS3 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 49/472 reads (10%) | catalogued as rs752917599, COSV57444390; called by muse, mutect2, varscan2
- ODF2L | c.1450G>C p.E484Q (on ENST00000317336; = p.E455Q on NM_020729.3) | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV99644804; called by muse, mutect2
- OR10A7 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58278934; called by muse, mutect2
- OR10K2 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59221735; called by muse, mutect2, varscan2
- OR1N1 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59195602; called by muse, mutect2
- OR2A2 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV68871930; called by muse, mutect2
- OR2J3 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV65849261; called by muse, mutect2, varscan2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 45/457 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by muse, mutect2
- OR2T1 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 9/255 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV63542346; called by muse, mutect2
- OR52N1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1348567067, COSV57693626; called by muse, mutect2
- OR8H2 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs1389752775, COSV57945951, COSV57946935; called by muse, mutect2
- OSMR | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs924689034, COSV57087311; called by muse, mutect2
- PAGE1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV65998260, COSV65998452; called by muse, mutect2
- PCDHA1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); catalogued as COSV65375241; called by muse, mutect2, varscan2
- PCDHA5 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.87); catalogued as rs868924111, COSV65349820; called by muse, mutect2, varscan2
- PCDHGA10 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.071); catalogued as COSV53978897, COSV99530329; called by muse, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2
- PENK | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 15/219 reads (7%) | catalogued as COSV59242166; called by muse, mutect2
- PER2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54523793; called by muse, mutect2
- PLA2R1 | c.3365G>A p.G1122E | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV51781740; called by muse, mutect2
- PLEC | c.13172C>T p.S4391F (on ENST00000322810 / NM_201380.4; = p.S4281F on NM_000445.5) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs913371011, COSV59656107; called by muse, mutect2
- PMFBP1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52827051; called by muse, mutect2
- PNPLA8 | c.1700C>T p.T567I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57553499; called by muse, mutect2
- POGLUT1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV55157353; called by muse, mutect2
- POLQ | c.5671C>T p.P1891S | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV51755862, COSV51756655; called by muse, mutect2, varscan2
- POM121C | c.1178C>T p.S393F (on ENST00000607367; = p.S151F on NM_001099415.3) | Missense Mutation (SNP) | VAF 53/432 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57547256; called by muse, mutect2, varscan2
- PPP1R10 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64739762; called by muse, mutect2
- PRCP | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as rs150477159; called by muse, mutect2, varscan2
- PRRC2B | c.3248G>A p.G1083E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV61939368; called by muse, mutect2
- PRSS55 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.989); catalogued as COSV60808728; called by muse, mutect2
- PSD4 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV55527857; called by muse, mutect2
- PTCHD1 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV65061488; called by muse, mutect2, varscan2
- PTPRT | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs781621750, COSV61963302; called by muse, mutect2, varscan2
- PYGL | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53586927; called by muse, mutect2
- RAB11FIP1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54761532; called by muse, mutect2, varscan2
- RALGAPA2 | c.5404G>A p.V1802M | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52502353; called by muse, mutect2
- RAPGEF5 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV59786815; called by muse, mutect2, varscan2
- RBFOX1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189994954, COSV60951723, COSV60957860; ClinVar: uncertain significance; called by muse, mutect2
- RDH12 | c.69G>A p.R23= | Splice Region (SNP) | VAF 12/218 reads (6%) | catalogued as COSV50822160; called by muse, mutect2
- RDH16 | c.954A>G p.*318Wext*2 | Nonstop Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100660070, COSV62458402; called by mutect2, varscan2
- RELA | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58015313; called by muse, mutect2
- RFPL3 | c.682G>A p.A228T (on ENST00000249007 / NM_001098535.1; = p.A199T on NM_006604.2) | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50750720; called by muse, mutect2, varscan2
- RIPOR3 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.325); catalogued as rs367985662; called by muse, mutect2, varscan2
- RORB | c.1360C>T p.P454S (on ENST00000396204 / NM_001365023.1; = p.P443S on NM_006914.4) | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65337509; called by muse, mutect2, varscan2
- RP1L1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61446183; called by muse, mutect2
- SAMD15 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV53626933; called by muse, mutect2
- SDHA | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.031); catalogued as COSV53766318, COSV53770526; called by muse, mutect2
- SDR16C5 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV58126416; called by muse, mutect2, varscan2
- SEL1L2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53154408; called by muse, mutect2
- SEL1L3 | c.2020G>A p.G674R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV53544340; called by muse, mutect2
- SEMA6D | c.2828A>G p.K943R (on ENST00000316364 / NM_153618.2; = p.K881R on NM_020858.2) | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as COSV60379907; called by muse, mutect2
- SERPINB3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52192589; called by muse, mutect2, varscan2
- SFTPD | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV64853383; called by muse, mutect2, varscan2
- SIGLEC11 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs1390916815, COSV70222055; called by muse, mutect2, varscan2
- SIGLEC8 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV58474543; called by muse, mutect2
- SLC17A8 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV60124909; called by muse, mutect2
- SLC27A6 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | catalogued as rs1376014840, COSV52484769, COSV52487137; called by muse, mutect2, varscan2
- SLC4A10 | c.1282C>T p.P428S (on ENST00000446997 / NM_001354461.2; = p.P398S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55786334; called by muse, mutect2
- SLC4A1AP | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.011); catalogued as COSV100389731; called by muse, mutect2
- SLC6A3 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV54366080, COSV99548557; called by muse, mutect2
- SLC7A14 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1269915150, COSV51585175; called by muse, mutect2
- SLFN11 | c.2032G>A p.G678R | Missense Mutation (SNP) | VAF 17/313 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1320928600, COSV57699464; called by muse, mutect2
- SLIT3 | c.3130C>T p.L1044F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1258399731, COSV60618508; called by muse, mutect2, varscan2
- SMAD7 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50988787; called by muse, mutect2
- SMC1B | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV62531114; called by muse, mutect2
- ST6GAL2 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 19/331 reads (6%) | PolyPhen benign (0.001); catalogued as rs1465277097, COSV64529610, COSV64530054; called by muse, mutect2
- TAF1B | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV55157638; called by muse, mutect2
- TENM1 | c.7225G>A p.E2409K | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64436151; called by muse, mutect2
- TENM1 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV64427547; called by muse, mutect2, varscan2
- THRAP3 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV63568641; called by muse, mutect2
- THSD7A | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV70267647; called by muse, mutect2
- TMC2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.271); catalogued as COSV62655183; called by muse, mutect2
- TNR | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.172); catalogued as COSV54896642; called by muse, mutect2
- TP63 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 9/127 reads (7%) | catalogued as COSV53210813; called by muse, mutect2
- TPO | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs373501176; called by muse, mutect2, varscan2
- TRMT44 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV67664317; called by muse, mutect2
- TRMT44 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV67664327; called by muse, mutect2
- TRPC1 | c.1699G>A p.E567K (on ENST00000476941 / NM_001251845.2; = p.E533K on NM_003304.4) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV56427092; called by muse, mutect2
- TSSK1B | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs374009361; called by muse, mutect2, varscan2
- TTBK2 | c.2788C>T p.R930W | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as rs1488362627, COSV51166742; called by muse, mutect2
- TTN | c.88697A>G p.K29566R (on ENST00000591111; = p.K22142R on NM_003319.4) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | PolyPhen probably damaging (0.994); catalogued as COSV60168304; called by muse, mutect2
- UNC13C | c.3907A>C p.K1303Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); catalogued as COSV52893358; called by muse, mutect2
- USH2A | c.14057C>T p.P4686L | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV56364876, COSV56443157; called by muse, mutect2
- USH2A | c.4646G>A p.R1549Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs190170807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP43 | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs755930719, COSV53304375; called by muse, mutect2, varscan2
- USP51 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV72351772; called by muse, mutect2
- VIL1 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | catalogued as COSV50290857; called by muse, mutect2, varscan2
- ZNF385D | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55763057; called by muse, mutect2, varscan2
- ZNF583 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52403301; called by muse, mutect2
- ZNF665 | c.1333G>A p.G445R (on ENST00000600412; = p.G510R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV67216096; called by muse, mutect2
- ASAH2 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.005); called by muse, mutect2
- CCNQ | c.161_164del p.I54Tfs*17 | Frame Shift Del (DEL) | VAF 24/241 reads (10%) | called by mutect2, pindel
- DNAH7 | c.6826C>T p.P2276S | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- IRS1 | c.3153dup p.E1052Rfs*29 | Frame Shift Ins (INS) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 74/1470 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.091); called by muse, mutect2
- KMT2D | c.14785C>T p.P4929S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- PLPP2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 15/454 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PRAMEF19 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 51/605 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- ADAMTS15 | c.2322C>T p.P774= | Silent (SNP) | VAF 13/143 reads (9%) | catalogued as COSV54507379; called by muse, mutect2
- ADGRE5 | c.1371A>G p.E457= (on ENST00000242786 / NM_078481.4; = p.E364= on NM_001784.5) | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as COSV54412540; called by muse, mutect2, varscan2
- ADGRG7 | c.358T>C p.L120= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV56298428; called by muse, mutect2
- ADH1B | c.423C>T p.F141= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as rs372727625; called by muse, mutect2, varscan2
- AFP | c.1035G>A p.G345= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV56925869; called by muse, mutect2
- ANKRD11 | c.4732C>T p.L1578= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV56364313; called by muse, mutect2
- APOBEC1 | c.582G>A p.K194= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV57549020, COSV57550510; called by muse, mutect2
- ARHGAP26 | c.372C>T p.I124= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as rs772422132, COSV50833541; called by muse, mutect2, varscan2
- ATRX | c.3429G>A p.K1143= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV64879164; called by muse, mutect2
- BPIFA1 | c.339C>T p.P113= | Silent (SNP) | VAF 22/456 reads (5%) | catalogued as COSV62824832; called by muse, mutect2
- BPIFB3 | c.717C>T p.S239= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV64957592; called by muse, mutect2
- C2 | c.834C>T p.S278= | Silent (SNP) | VAF 35/358 reads (10%) | catalogued as COSV54961402; called by muse, mutect2
- CABLES2 | c.1140C>T p.P380= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as rs577803640, COSV54156563; called by muse, mutect2
- CCT6B | c.9G>T p.A3= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV58490142; called by muse, mutect2, varscan2
- CES5A | c.1335G>A p.T445= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs747962253, COSV51867987, COSV51871652; called by muse, mutect2
- CFH | c.1926G>A p.K642= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1397169050, COSV66410353; called by muse, mutect2
- CHMP6 | c.429C>T p.L143= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV57327638; called by muse, mutect2, varscan2
- CLK2 | c.1255C>T p.L419= (on ENST00000368361 / NM_001294339.2; = p.L418= on NM_003993.4) | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as COSV56946248; called by muse, mutect2
- CNTNAP5 | c.2814G>A p.Q938= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as rs1399512654, COSV70494450; called by muse, mutect2, varscan2
- COQ8B | c.1083C>T p.F361= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV54687750; called by muse, mutect2
- CWH43 | c.306C>T p.S102= | Silent (SNP) | VAF 26/296 reads (9%) | catalogued as COSV56940618; called by muse, mutect2
- CYP1A2 | c.1116C>T p.I372= | Silent (SNP) | VAF 24/282 reads (9%) | catalogued as rs1299423148, COSV59660173; called by muse, mutect2
- CYP2C8 | c.534C>T p.I178= | Silent (SNP) | VAF 13/162 reads (8%) | catalogued as rs371717605; called by muse, mutect2
- DDX17 | c.660G>A p.G220= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs148438451; called by muse, mutect2, varscan2
- DGKG | c.1437C>T p.F479= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV53967725; called by muse, mutect2
- DIDO1 | c.3165C>T p.T1055= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV56627121, COSV99824310; called by muse, mutect2, varscan2
- DNASE2 | c.582C>T p.F194= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV52241283; called by muse, mutect2, varscan2
- EEPD1 | c.1230C>T p.L410= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV54200201; called by muse, mutect2
- EFHB | c.1296A>G p.A432= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV55549901; called by muse, mutect2
- F5 | c.1908G>A p.R636= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV63125668; called by muse, mutect2, varscan2
- FARSB | c.375T>C p.V125= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV56050908; called by muse, mutect2, varscan2
- FAT4 | c.12714C>T p.A4238= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV58694329; called by muse, mutect2
- FGA | c.531C>T p.I177= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV57395058, COSV57397731; called by muse, mutect2, varscan2
- FMOD | c.357C>T p.S119= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV61610278; called by muse, mutect2
- FYCO1 | c.1326G>A p.R442= | Silent (SNP) | VAF 37/466 reads (8%) | catalogued as COSV56117281; called by muse, mutect2
- GCM2 | c.879G>A p.K293= | Silent (SNP) | VAF 14/386 reads (4%) | catalogued as COSV65275991; called by muse, mutect2
- GIMAP6 | c.156G>A p.G52= | Silent (SNP) | VAF 95/639 reads (15%) | catalogued as COSV61032975; called by muse, mutect2, varscan2
- GJA8 | c.822C>T p.I274= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs781834904, COSV53788326; called by muse, mutect2
- GPR83 | c.1140C>T p.S380= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs760650059, COSV54719446; called by muse, mutect2
- GRIA1 | c.588G>A p.K196= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as rs141629018, COSV53611235; called by muse, mutect2
- GRXCR1 | c.60C>T p.I20= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as rs267600162, COSV67669835; called by muse, mutect2
- GSG1L | c.525C>T p.F175= (on ENST00000447459 / NM_001109763.2; = p.F20= on NM_144675.2) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs899540161, COSV66577830; called by muse, mutect2, varscan2
- GUCY1A2 | c.2178C>T p.F726= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV56492172; called by muse, mutect2
- HECTD4 | c.13092C>T p.I4364= | Silent (SNP) | VAF 21/194 reads (11%) | catalogued as rs1350872417, COSV66394775; called by muse, mutect2, varscan2
- HECW2 | c.3939C>T p.I1313= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV53664884; called by muse, mutect2
- HUWE1 | c.12114C>T p.S4038= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs782764055, COSV53353038; called by muse, mutect2
- IGSF1 | c.804C>T p.S268= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV63838474, COSV63839437; called by muse, mutect2
- IL9R | c.192C>T p.I64= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs1441044045, COSV54900647, COSV99730240; called by muse, mutect2, varscan2
- INTS1 | c.4968C>T p.F1656= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV67177423; called by muse, mutect2, varscan2
- IQCH | c.2922C>T p.I974= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV60055763; called by muse, mutect2
- ITPR3 | c.114G>A p.V38= | Silent (SNP) | VAF 46/381 reads (12%) | catalogued as COSV65411536; called by muse, mutect2, varscan2
- KRT6B | c.1527G>A p.L509= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV52884704; called by muse, mutect2
- KRTAP24-1 | c.192C>T p.S64= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as COSV61089779; called by muse, mutect2
- LAMP2 | c.1125C>T p.F375= | Silent (SNP) | VAF 24/336 reads (7%) | catalogued as rs746288560, COSV99568999; called by muse, mutect2
- LIMK1 | c.1197C>T p.F399= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV60282743; called by muse, mutect2, varscan2
- LMNA | c.1038C>T p.A346= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as rs1019030652, COSV100738690, COSV100738923; called by muse, mutect2
- MAGEA6 | c.153G>A p.G51= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs1168092457, COSV100262798; called by muse, mutect2
- MAGEC1 | c.2469G>A p.S823= | Silent (SNP) | VAF 56/451 reads (12%) | catalogued as COSV53576312; called by muse, mutect2, varscan2
- MAMLD1 | c.867C>T p.L289= | Silent (SNP) | VAF 11/178 reads (6%) | catalogued as COSV53377507; called by muse, mutect2
- MAP3K10 | c.1422C>T p.I474= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99454969; called by muse, mutect2
- MC2R | c.477G>A p.T159= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as rs141290578, COSV59618010; called by muse, mutect2
- MMRN1 | c.540G>A p.R180= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV53339343; called by muse, mutect2, varscan2
- MUC4 | c.12861C>T p.S4287= (on ENST00000463781 / NM_018406.7; = p.S51= on NM_004532.6) | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as rs755984623, COSV57789431; called by muse, mutect2
- MYH2 | c.4941G>A p.R1647= | Silent (SNP) | VAF 29/265 reads (11%) | catalogued as COSV55432633; called by muse, mutect2, varscan2
- MYH2 | c.1542C>T p.I514= | Silent (SNP) | VAF 24/308 reads (8%) | catalogued as rs1040993470, COSV55440907; called by muse, mutect2
- MYLK | c.1227G>A p.R409= | Silent (SNP) | VAF 8/177 reads (5%) | catalogued as COSV60614356; called by muse, mutect2
- NLGN4X | c.2061C>T p.F687= | Silent (SNP) | VAF 19/214 reads (9%) | catalogued as rs1169457820, COSV52007306; called by muse, mutect2
- NLRP11 | c.2049G>A p.K683= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV64088016; called by muse, mutect2
- NLRP5 | c.2679C>T p.S893= | Silent (SNP) | VAF 6/119 reads (5%) | catalogued as COSV66765801; called by muse, mutect2
- NSD3 | c.1446C>T p.S482= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV57620320; called by muse, mutect2
- ODF2L | c.1449G>A p.Q483= (on ENST00000317336; = p.Q454= on NM_020729.3) | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV99644811; called by muse, mutect2, varscan2
- OGDH | c.1125C>T p.S375= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as rs1359951023, COSV56052913; called by muse, mutect2, varscan2
- OR10H4 | c.642C>T p.F214= | Silent (SNP) | VAF 32/380 reads (8%) | catalogued as rs1360607799, COSV59061641; called by muse, mutect2
- OR1N2 | c.642C>A p.L214= | Silent (SNP) | VAF 35/271 reads (13%) | catalogued as COSV101031482; called by muse, mutect2, varscan2
- OR1N2 | c.643C>T p.L215= | Silent (SNP) | VAF 34/275 reads (12%) | catalogued as COSV101031483; called by muse, mutect2, varscan2
- OR2W3 | c.96G>A p.L32= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as COSV64457393; called by muse, mutect2, varscan2
- OR56A1 | c.309G>A p.Q103= | Silent (SNP) | VAF 6/135 reads (4%) | catalogued as COSV57363101; called by muse, mutect2
- OR5B21 | c.180C>T p.F60= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV64481650; called by muse, mutect2
- OSER1 | c.318C>T p.L106= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV99667474; called by muse, mutect2
- P4HA2 | c.630G>T p.L210= | Silent (SNP) | VAF 29/265 reads (11%) | catalogued as COSV51327070; called by muse, mutect2, varscan2
- PALM | c.687C>T p.S229= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs1359421246, COSV52769026; called by muse, mutect2, varscan2
- PCDHA12 | c.1365C>T p.F455= | Silent (SNP) | VAF 29/215 reads (13%) | catalogued as rs782753877, COSV56480719; called by muse, mutect2, varscan2
- PCDHA13 | c.930C>T p.F310= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV56498969; called by muse, mutect2, varscan2
- PCDHA3 | c.654G>A p.G218= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV65368474; called by muse, mutect2, varscan2
- PCDHB3 | c.2322C>T p.F774= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as rs782811619, COSV50566253, COSV50575056; called by muse, mutect2, varscan2
- PCDHB8 | c.1848C>T p.F616= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as rs267600429, COSV50786147; called by muse, mutect2
- PCDHGB4 | c.1350C>T p.F450= | Silent (SNP) | VAF 16/276 reads (6%) | catalogued as COSV53978886; called by muse, mutect2
- PGK1 | c.1206C>T p.L402= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV59371624; called by muse, mutect2
- PLCB1 | c.978C>T p.F326= | Silent (SNP) | VAF 38/238 reads (16%) | catalogued as COSV100570047, COSV62049958, COSV62058176; called by muse, mutect2, varscan2
- PLEKHA2 | c.525C>T p.S175= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs112121731, COSV66242969; called by muse, mutect2, varscan2
- PLEKHM1 | c.2118C>T p.S706= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV69599170; called by muse, mutect2
- PRX | c.1200C>T p.L400= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV52531279; called by muse, mutect2
- PTPRN2 | c.2229C>T p.N743= | Silent (SNP) | VAF 82/513 reads (16%) | catalogued as rs1435727553, COSV67047332; called by muse, mutect2, varscan2
- RAB4A | c.363C>T p.I121= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV64207706; called by muse, mutect2, varscan2
- RAI1 | c.1998C>T p.A666= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV55395142; called by muse, mutect2
- RBPJL | c.213C>T p.I71= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1161469437, COSV100636899, COSV59214377; called by muse, mutect2
- RPS21 | c.30C>T p.D10= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1255393667, COSV54157383; called by muse, mutect2
- SAMD9 | c.2016C>T p.F672= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV66076405; called by muse, mutect2, varscan2
- SHPRH | c.1497C>T p.I499= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV51612862; called by mutect2, varscan2
- SIRPG | c.288G>A p.K96= | Silent (SNP) | VAF 35/231 reads (15%) | catalogued as COSV53808466; called by muse, mutect2, varscan2
- SLC17A2 | c.399C>T p.T133= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV55350808, COSV55353068; called by muse, mutect2, varscan2
- SLC4A1 | c.567C>T p.L189= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as rs746103796, COSV52259262, COSV52261356; called by muse, mutect2, varscan2
- SLC4A1AP | c.132G>A p.K44= | Silent (SNP) | VAF 17/233 reads (7%) | catalogued as COSV100389730; called by muse, mutect2
- SLIT1 | c.1248G>A p.K416= | Silent (SNP) | VAF 15/213 reads (7%) | catalogued as COSV56592837; called by muse, mutect2
- SLIT2 | c.2892C>T p.N964= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1337316760, COSV56580187; called by muse, mutect2
- SOX5 | c.843C>T p.P281= | Silent (SNP) | VAF 21/259 reads (8%) | catalogued as rs760608804, COSV100508809, COSV58636393; called by muse, mutect2
- SPAG17 | c.4584C>T p.Y1528= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV60462217; called by muse, mutect2
- SPHKAP | c.1719G>A p.L573= | Silent (SNP) | VAF 21/235 reads (9%) | catalogued as rs1196541914, COSV60884711; called by muse, mutect2
- STK39 | c.465C>T p.N155= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV63599123; called by muse, mutect2
- SV2A | c.1833G>A p.G611= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV64964846; called by muse, mutect2, varscan2
- TENM4 | c.7158G>A p.G2386= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as rs1217043243, COSV53643315; called by muse, mutect2
- TEX15 | c.3951C>T p.F1317= (on ENST00000256246; = p.F1700= on NM_001350162.2) | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV56348125; called by muse, mutect2
- TIGIT | c.108G>A p.E36= | Silent (SNP) | VAF 14/306 reads (5%) | catalogued as COSV67329122; called by muse, mutect2
- TM9SF4 | c.1770C>T p.F590= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as rs1207506997, COSV54106267; called by muse, mutect2
- TNPO3 | c.2175C>T p.L725= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs958453001, COSV55283782; called by muse, mutect2
- TP63 | c.543C>T p.F181= | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as rs1490473342, COSV99289407; called by muse, mutect2
- TRIM6 | c.318C>T p.L106= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as rs932686457, COSV53475523, COSV53477158; called by muse, mutect2
- TRPM6 | c.2775C>T p.F925= | Silent (SNP) | VAF 28/210 reads (13%) | catalogued as rs745674352, COSV62510894; called by muse, mutect2, varscan2
- TTN | c.12417C>T p.T4139= (on ENST00000591111; = p.T4093= on NM_003319.4) | Silent (SNP) | VAF 10/199 reads (5%) | catalogued as COSV100635248; called by muse, mutect2
- ZAN | c.4770C>T p.R1590= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs534625824, COSV61811220; called by muse, mutect2, varscan2
- ZC3H18 | c.2034C>T p.P678= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV56325976; called by muse, mutect2, varscan2
- ZNF229 | c.2229C>T p.H743= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs373859995; called by muse, mutect2, varscan2
- ZNF318 | c.4249C>T p.L1417= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV58934273; called by muse, mutect2, varscan2
- ZNF385B | c.64C>T p.L22= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV69801875, COSV69804156; called by muse, mutect2
- ZNF76 | c.615C>T p.A205= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as COSV57591868; called by muse, mutect2, varscan2
- AC245047.1 | n.80G>A | RNA (SNP) | VAF 30/330 reads (9%) | catalogued as rs782579559; called by muse, mutect2
- C12orf77 | n.256G>A | RNA (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- CCNQP1 | n.252G>A | RNA (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- CCNQP1 | n.562A>T | RNA (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2, varscan2
- CCNQP1 | n.563G>A | RNA (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2
- IFRD2 | c.-51C>T | 5'UTR (SNP) | VAF 9/76 reads (12%) | catalogued as COSV57114395; called by muse, mutect2, varscan2
- KIR3DX1 | n.549C>T | RNA (SNP) | VAF 11/102 reads (11%) | catalogued as rs1191972900, COSV99683398; called by muse, mutect2, varscan2
- MFRP | chr11:119346311 G>A | 5'Flank (SNP) | VAF 7/47 reads (15%) | catalogued as COSV64128717; called by muse, mutect2, varscan2
- NRG1 | c.502+30846C>T | Intron (SNP) | VAF 8/105 reads (8%) | catalogued as COSV55166836; called by muse, mutect2
